TCGA case TCGA-02-0321 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/05875fe7-ad0e-45e1-a880-9aece4fea3b9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 301 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 74.3 years (27,125 days); Year of diagnosis: 1995; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 74.5 years (27,198 days); Days to diagnosis: 73 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 74 days.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 73 (post initial treatment): Progression or recurrence: Yes; Days to progression: 73 days.
- Days to follow up: 301 days; Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0321-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-02-0321-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0; Percent lymphocyte infiltration: 0.
  Slide TCGA-02-0321-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 0; Percent lymphocyte infiltration: 0.
- Sample TCGA-02-0321-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 301 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 301 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 73 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-02-0321-01): tumor purity 0.46, ploidy 1.92, whole-genome doublings 0 (call status: legacy_call).
